Somatic mutation profile of tumor specimen C3N-01989-02 (aliquot CPT0112230009) from CPTAC case C3N-01989, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 70.4 years (25,700 days).
Specimen C3N-01989-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 257e7501-9074-4aca-9e8e-deaadb9434ae.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01989-71 (Blood Derived Normal), aliquot CPT0112340002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b6ed08df-f43b-4128-8399-11b8d3817510

The open-access MAF lists 120 somatic variants for this specimen: 82 protein-altering or splice-affecting, 17 silent, 21 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 54, Silent 17, Intron 12, Frame Shift Del 11, Nonsense Mutation 5, 5'Flank 5, Splice Site 4, Frame Shift Ins 4, In Frame Del 3, 5'UTR 2, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA13 | c.14563G>T p.A4855S | Missense Mutation (SNP) | VAF 17/297 reads (6%) | SIFT tolerated (0.46); PolyPhen benign (0.087); catalogued as COSV101291164; called by muse, mutect2
- CLCA2 | c.189A>C p.E63D | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.59); PolyPhen benign (0.02); catalogued as rs897669169, COSV65287834; called by muse, mutect2
- COL7A1 | c.8304+1G>T p.X2768_splice | Splice Site (SNP) | VAF 126/260 reads (48%) | catalogued as HS090004; called by muse, mutect2, varscan2
- CPXCR1 | c.271C>G p.L91V | Missense Mutation (SNP) | VAF 52/151 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.134); catalogued as COSV52163112; called by muse, mutect2, varscan2
- EXOC3L4 | c.1466+1G>A p.X489_splice | Splice Site (SNP) | VAF 56/143 reads (39%) | catalogued as COSV66295526; called by muse, mutect2, varscan2
- FRAS1 | c.4063G>T p.A1355S | Missense Mutation (SNP) | VAF 11/182 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); catalogued as COSV53662939; called by muse, mutect2
- HMGCL | c.494G>A p.R165Q | Missense Mutation (SNP) | VAF 121/408 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199587895, CM092723, COSV52525051, COSV99354166; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IGFALS | c.1724C>T p.A575V | Missense Mutation (SNP) | VAF 105/314 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs770945305; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ITGA2 | c.780-1del p.X260_splice | Splice Site (DEL) | VAF 79/288 reads (27%) | catalogued as COSV56861508; called by mutect2, pindel, varscan2
- KRT13 | c.772G>A p.V258I | Missense Mutation (SNP) | VAF 123/324 reads (38%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.669); catalogued as rs1218299372; called by muse, mutect2, varscan2
- MAPK8IP3 | c.1016C>T p.S339F | Missense Mutation (SNP) | VAF 68/198 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51724238; called by muse, mutect2, varscan2
- MED12 | c.4069C>T p.R1357C | Missense Mutation (SNP) | VAF 154/538 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1474736821, COSV61347292; called by muse, mutect2, varscan2
- NLRP3 | c.1970C>T p.T657I | Missense Mutation (SNP) | VAF 103/327 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as rs201875324, COSV60226013; called by muse, mutect2, varscan2
- NUGGC | c.1804C>A p.H602N | Missense Mutation (SNP) | VAF 73/202 reads (36%) | SIFT tolerated (0.31); PolyPhen benign (0.439); catalogued as COSV100429725; called by muse, mutect2, varscan2
- NYAP2 | c.808G>A p.E270K | Missense Mutation (SNP) | VAF 79/243 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55997485; called by muse, mutect2, varscan2
- PCDHGA8 | c.2047G>T p.D683Y | Missense Mutation (SNP) | VAF 107/279 reads (38%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.077); catalogued as COSV54001526; called by muse, mutect2, varscan2
- PRR19 | c.589C>A p.P197T | Missense Mutation (SNP) | VAF 114/353 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as COSV56628201; called by muse, mutect2, varscan2
- PTOV1 | c.958C>T p.R320W | Missense Mutation (SNP) | VAF 44/137 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.212); catalogued as rs775515238; called by muse, mutect2, varscan2
- SMCHD1 | c.823_825del p.K275del | In Frame Del (DEL) | VAF 9/48 reads (19%) | catalogued as rs746679988; called by pindel, varscan2
- TRAM1 | c.656G>A p.G219E | Missense Mutation (SNP) | VAF 41/106 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV51599697; called by muse, mutect2, varscan2
- TSPO2 | c.47C>G p.P16R | Missense Mutation (SNP) | VAF 60/186 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.898); catalogued as COSV55112004; called by muse, mutect2, varscan2
- VHL | c.508del p.V170Sfs*32 | Frame Shift Del (DEL) | VAF 166/369 reads (45%) | catalogued as CM941385; called by mutect2, pindel, varscan2
- ZNF143 | c.1019C>T p.T340I | Missense Mutation (SNP) | VAF 26/286 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.383); catalogued as rs774170725; called by muse, mutect2
- ZNF831 | c.943del p.L315Cfs*219 | Frame Shift Del (DEL) | VAF 51/176 reads (29%) | catalogued as COSV64044565; called by mutect2, pindel, varscan2
- ADAM17 | c.963T>A p.F321L | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- AGRN | c.4628C>G p.S1543C | Missense Mutation (SNP) | VAF 108/317 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.62); called by muse, mutect2, varscan2
- ASPM | c.4339G>A p.V1447I | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATP2B1 | c.1049A>T p.K350M | Missense Mutation (SNP) | VAF 42/143 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- BANK1 | c.1921A>T p.R641* | Nonsense Mutation (SNP) | VAF 20/46 reads (43%) | called by muse, mutect2, varscan2
- BFSP1 | c.1172T>A p.L391* | Nonsense Mutation (SNP) | VAF 152/483 reads (31%) | called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.2676dup p.G893Rfs*12 | Frame Shift Ins (INS) | VAF 140/474 reads (30%) | called by mutect2, pindel, varscan2
- BMP3 | c.381T>G p.I127M | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); called by muse, mutect2, varscan2
- BRIP1 | c.2347G>C p.G783R | Missense Mutation (SNP) | VAF 127/414 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CCDC88C | c.3587del p.K1196Rfs*22 | Frame Shift Del (DEL) | VAF 60/202 reads (30%) | called by mutect2, pindel
- CEP295 | c.4894T>G p.L1632V | Missense Mutation (SNP) | VAF 35/182 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- CFAP97 | c.432del p.K144Nfs*4 | Frame Shift Del (DEL) | VAF 80/275 reads (29%) | called by mutect2, pindel, varscan2
- CHST7 | c.731A>T p.Y244F | Missense Mutation (SNP) | VAF 11/288 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CLPSL2 | c.174del p.R59Gfs*4 | Frame Shift Del (DEL) | VAF 59/196 reads (30%) | called by mutect2, pindel, varscan2
- COL7A1 | c.8304G>T p.Q2768H | Missense Mutation (SNP) | VAF 126/257 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- CYFIP2 | c.638T>C p.F213S | Missense Mutation (SNP) | VAF 41/121 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.693); called by muse, mutect2, varscan2
- DNAH10 | c.11205C>A p.Y3735* (on ENST00000409039; = p.Y3674* on NM_207437.3) | Nonsense Mutation (SNP) | VAF 29/136 reads (21%) | called by muse, mutect2, varscan2
- DNAJC13 | c.5653del p.D1885Ifs*3 | Frame Shift Del (DEL) | VAF 42/165 reads (25%) | called by mutect2, pindel, varscan2
- EEF2K | c.1226A>T p.H409L | Missense Mutation (SNP) | VAF 57/163 reads (35%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- EGFR | c.1538A>G p.E513G | Missense Mutation (SNP) | VAF 70/197 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- EIF4G2 | c.184T>C p.S62P | Missense Mutation (SNP) | VAF 158/487 reads (32%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.61); called by muse, mutect2, varscan2
- ELANE | c.89T>C p.I30T | Missense Mutation (SNP) | VAF 72/181 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ERCC1 | c.489C>G p.N163K | Missense Mutation (SNP) | VAF 146/444 reads (33%) | SIFT tolerated (0.53); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- FSTL4 | c.1445T>C p.I482T | Missense Mutation (SNP) | VAF 49/134 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- GAL3ST3 | c.360del p.R121Gfs*119 | Frame Shift Del (DEL) | VAF 79/219 reads (36%) | called by mutect2, pindel, varscan2
- HMCN2 | c.11195+2_11195+3dup | Frame Shift Ins (INS) | VAF 12/48 reads (25%) | called by mutect2, pindel, varscan2
- HOXA9 | c.290_294delinsGT p.P97_V98delinsR | In Frame Del (DEL) | VAF 8/58 reads (14%) | called by pindel, varscan2*
- IER2 | c.580C>A p.P194T | Missense Mutation (SNP) | VAF 66/205 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- IL13RA2 | c.662A>T p.K221M | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.407); called by muse, varscan2
- KCNG3 | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 46/148 reads (31%) | SIFT tolerated (0.66); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- KLHL40 | c.1454C>T p.P485L | Missense Mutation (SNP) | VAF 75/144 reads (52%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.653); called by muse, mutect2, varscan2
- LRRC49 | c.105+2T>G p.X35_splice | Splice Site (SNP) | VAF 55/152 reads (36%) | called by muse, mutect2, varscan2
- MFSD14B | c.274C>A p.L92I | Missense Mutation (SNP) | VAF 166/530 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- MYO15B | c.8746A>T p.S2916C | Missense Mutation (SNP) | VAF 51/158 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- MZF1 | c.902T>C p.F301S | Missense Mutation (SNP) | VAF 74/222 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NCR2 | c.59_60del p.Q20Rfs*36 | Frame Shift Del (DEL) | VAF 28/86 reads (33%) | called by mutect2, pindel, varscan2
- OR2K2 | c.809G>C p.G270A (on ENST00000374428; = p.G241A on NM_205859.2) | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- PBRM1 | c.2559dup p.M854Dfs*10 | Frame Shift Ins (INS) | VAF 20/44 reads (45%) | called by mutect2, pindel, varscan2
- PKHD1 | c.51A>C p.A17= | Splice Region (SNP) | VAF 89/284 reads (31%) | called by muse, mutect2, varscan2
- PMS1 | c.1827G>C p.W609C | Missense Mutation (SNP) | VAF 64/189 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- POC1A | c.10C>A p.P4T | Missense Mutation (SNP) | VAF 53/91 reads (58%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRRX1 | c.94A>T p.K32* | Nonsense Mutation (SNP) | VAF 90/290 reads (31%) | called by muse, mutect2, varscan2
- RMC1 | c.208_209del p.I70* | Frame Shift Del (DEL) | VAF 43/138 reads (31%) | called by mutect2, pindel, varscan2
- SCYL2 | c.1650del p.Y550* | Frame Shift Del (DEL) | VAF 30/104 reads (29%) | called by mutect2, pindel, varscan2
- SFRP4 | c.563C>T p.A188V | Missense Mutation (SNP) | VAF 61/185 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- SFXN5 | c.218G>T p.G73V | Missense Mutation (SNP) | VAF 43/140 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- SGK1 | c.180C>A p.F60L | Missense Mutation (SNP) | VAF 54/145 reads (37%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- SHANK1 | c.767G>A p.C256Y | Missense Mutation (SNP) | VAF 80/233 reads (34%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- SIGLECL1 | c.132_135delinsGT p.P45Cfs*22 | Frame Shift Del (DEL) | VAF 71/302 reads (24%) | called by pindel, varscan2*
- SLC9A3 | c.14_28del p.G5_P9del | In Frame Del (DEL) | VAF 51/110 reads (46%) | called by mutect2, pindel, varscan2
- SPATA31A1 | c.602C>G p.P201R | Missense Mutation (SNP) | VAF 60/393 reads (15%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.605); called by muse, mutect2, varscan2
- SPATA31D1 | c.2304T>A p.N768K | Missense Mutation (SNP) | VAF 159/503 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- TEX45 | c.50G>T p.R17L | Missense Mutation (SNP) | VAF 70/194 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, varscan2
- TP53BP1 | c.122G>A p.S41N | Missense Mutation (SNP) | VAF 45/152 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- UBE2QL1 | c.389dup p.S131Vfs*8 | Frame Shift Ins (INS) | VAF 26/83 reads (31%) | called by mutect2, pindel, varscan2
- ZC3H13 | c.443G>T p.R148I | Missense Mutation (SNP) | VAF 58/201 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZNF654 | c.2324T>G p.L775* | Nonsense Mutation (SNP) | VAF 53/145 reads (37%) | called by muse, mutect2, varscan2
- ZNF808 | c.652C>G p.L218V | Missense Mutation (SNP) | VAF 71/241 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- AHCTF1 | c.6753A>T p.I2251= (on ENST00000366508; = p.I2225= on NM_015446.5) | Silent (SNP) | VAF 109/317 reads (34%) | called by muse, mutect2, varscan2
- ANKS1B | c.285T>A p.P95= | Silent (SNP) | VAF 68/218 reads (31%) | called by muse, mutect2, varscan2
- ATP13A3 | c.2511G>C p.V837= | Silent (SNP) | VAF 27/73 reads (37%) | catalogued as COSV55466797; called by muse, mutect2, varscan2
- C1orf112 | c.2256A>C p.V752= | Silent (SNP) | VAF 30/96 reads (31%) | called by muse, varscan2
- CAMK2G | c.573T>C p.Y191= | Silent (SNP) | VAF 71/210 reads (34%) | called by muse, mutect2, varscan2
- CTSA | c.276T>C p.D92= | Silent (SNP) | VAF 164/477 reads (34%) | called by muse, mutect2, varscan2
- DUOX2 | c.3501C>G p.V1167= | Silent (SNP) | VAF 116/363 reads (32%) | called by muse, mutect2, varscan2
- FSIP2 | c.4617C>T p.S1539= | Silent (SNP) | VAF 52/188 reads (28%) | called by muse, mutect2, varscan2
- LRIT2 | c.1410G>A p.L470= | Silent (SNP) | VAF 57/150 reads (38%) | called by muse, mutect2, varscan2
- MMD2 | c.171C>T p.Y57= | Silent (SNP) | VAF 88/271 reads (32%) | catalogued as rs377117335; called by muse, mutect2, varscan2
- NFE2L1 | c.1470A>T p.L490= | Silent (SNP) | VAF 89/236 reads (38%) | called by muse, mutect2, varscan2
- NR1I2 | c.105C>A p.V35= | Silent (SNP) | VAF 130/360 reads (36%) | called by muse, mutect2, varscan2
- POU3F4 | c.114C>T p.L38= | Silent (SNP) | VAF 99/280 reads (35%) | catalogued as rs769490882; called by muse, mutect2, varscan2
- PRSS36 | c.48C>T p.P16= | Silent (SNP) | VAF 92/298 reads (31%) | called by muse, mutect2, varscan2
- USP17L2 | c.1110C>G p.L370= | Silent (SNP) | VAF 251/2032 reads (12%) | catalogued as rs1486840146, COSV61555557; called by muse, mutect2, varscan2
- WNT3A | c.255G>A p.R85= | Silent (SNP) | VAF 77/192 reads (40%) | catalogued as rs932879941; called by muse, mutect2, varscan2
- ZNF398 | c.435T>C p.F145= | Silent (SNP) | VAF 46/123 reads (37%) | called by muse, mutect2, varscan2
- ABR | c.1962-253G>C | Intron (SNP) | VAF 65/167 reads (39%) | catalogued as rs539993519; called by muse, mutect2, varscan2
- AL133467.6 | chr14:95668372 A>G | 5'Flank (SNP) | VAF 107/343 reads (31%) | called by muse, mutect2, varscan2
- CCDC162P | n.6504T>A | RNA (SNP) | VAF 27/95 reads (28%) | called by muse, mutect2, varscan2
- CLLU1 | chr12:92421063 T>A | 5'Flank (SNP) | VAF 57/159 reads (36%) | called by muse, mutect2, varscan2
- CPSF4 | c.155-277_155-276del | Intron (DEL) | VAF 26/94 reads (28%) | called by mutect2, pindel, varscan2
- DYNC1H1 | c.6618+9G>T | Intron (SNP) | VAF 149/460 reads (32%) | called by muse, mutect2, varscan2
- HUWE1 | c.862+20del | Intron (DEL) | VAF 66/246 reads (27%) | called by mutect2, pindel, varscan2
- MARCHF1 | c.-322-85616A>T | Intron (SNP) | VAF 113/348 reads (32%) | called by muse, mutect2, varscan2
- PLG | c.292+21C>A | Intron (SNP) | VAF 71/195 reads (36%) | called by muse, mutect2, varscan2
- PPP2R5E | c.354+13T>G | Intron (SNP) | VAF 37/102 reads (36%) | called by muse, mutect2, varscan2
- PRR12 | chr19:49595349 G>A | 5'Flank (SNP) | VAF 34/97 reads (35%) | catalogued as rs1230114114; called by muse, mutect2, varscan2
- PRR12 | chr19:49595350 C>T | 5'Flank (SNP) | VAF 35/96 reads (36%) | catalogued as rs771631775; called by muse, mutect2, varscan2
- RAB39B | c.-29G>T | 5'UTR (SNP) | VAF 59/198 reads (30%) | catalogued as COSV101034872; called by muse, mutect2, varscan2
- SFR1 | c.-18T>G | 5'UTR (SNP) | VAF 62/208 reads (30%) | catalogued as rs764058608; called by muse, mutect2, varscan2
- SPAG8 | c.*252A>C | 3'UTR (SNP) | VAF 20/41 reads (49%) | called by muse, varscan2
- TMEM150A | c.113+65T>C | Intron (SNP) | VAF 61/202 reads (30%) | called by muse, mutect2, varscan2
- TNNT2 | c.234-50G>A | Intron (SNP) | VAF 76/185 reads (41%) | called by muse, mutect2, varscan2
- TRIM73 | chr7:75395014 G>T | 5'Flank (SNP) | VAF 17/52 reads (33%) | called by mutect2, varscan2
- UHRF1 | c.-10-1286del | Intron (DEL) | VAF 72/285 reads (25%) | called by mutect2, pindel, varscan2
- UHRF1BP1L | c.44+13873C>T | Intron (SNP) | VAF 50/153 reads (33%) | catalogued as rs1176681286; called by muse, mutect2, varscan2
- VCAN | c.4004-20G>C | Intron (SNP) | VAF 9/19 reads (47%) | catalogued as COSV54109080, COSV99427097; called by muse, mutect2, varscan2
